MMRF case MMRF_2352 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/91bd88fa-1279-4afe-8be1-5f2ad7869c5d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 60.6 years (22,131 days); ISS stage: III; Days to last known disease status: 820 days (2.2 years); Days to last follow up: 820 days (2.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 139 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 3 days; Days to treatment end: 139 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 149 days; Days to treatment end: 150 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 151 days; Days to treatment end: 151 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 307 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1560 mg/dL; Immunoglobulin G 5.14 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 10.4 µg/mL; Hemoglobin 7.01 mmol/L; Leukocytes 6.76 ×10⁹/L; Absolute Neutrophil 4.81 ×10⁹/L; Platelets 310 ×10⁹/L; Creatinine 318 µmol/L; Blood Urea Nitrogen 23.9 mmol/L; Calcium 2.5 mmol/L; Albumin 39 g/L; Total Protein 8 g/dL; Glucose 5.45 mmol/L.
- Day 94 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.26 mg/dL; Hemoglobin 6.57 mmol/L; Leukocytes 6.38 ×10⁹/L; Absolute Neutrophil 6.04 ×10⁹/L; Platelets 299 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.1 mmol/L; Albumin 35 g/L; Total Protein 6.4 g/dL; Glucose 5.17 mmol/L.
- Day 185 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.86 mg/dL; Immunoglobulin G 3.77 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 2.5 µg/mL; Lactate Dehydrogenase 3.43 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 118 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.25 mmol/L; Albumin 33 g/L; Total Protein 6.9 g/dL; Glucose 7.1 mmol/L.
- Day 260 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.28 mg/dL; Immunoglobulin G 7.16 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.54 g/L; Beta 2 Microglobulin 3 µg/mL; Lactate Dehydrogenase 3.6 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 5.21 ×10⁹/L; Absolute Neutrophil 3.38 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 131 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.13 mmol/L; Albumin 41 g/L; Total Protein 7.3 g/dL; Glucose 4.79 mmol/L.
- Day 372 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.82 mg/dL; Immunoglobulin G 6.66 g/L; Immunoglobulin A 0.65 g/L; Immunoglobulin M 0.52 g/L; Hemoglobin 7.56 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 98 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 1.95 mmol/L; Albumin 36 g/L; Total Protein 6.1 g/dL; Glucose 4.73 mmol/L.
- Day 470 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.46 mg/dL; Immunoglobulin G 6.72 g/L; Immunoglobulin A 0.66 g/L; Immunoglobulin M 0.51 g/L; Hemoglobin 8.06 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 109 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2 mmol/L; Albumin 34 g/L; Total Protein 6.1 g/dL; Glucose 5.61 mmol/L.
- Day 554 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.75 mg/dL; Immunoglobulin G 6.31 g/L; Immunoglobulin A 0.96 g/L; Immunoglobulin M 0.24 g/L; Hemoglobin 7.38 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 83 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.18 mmol/L; Albumin 34 g/L; Total Protein 6.2 g/dL; Glucose 4.73 mmol/L.
- Day 638 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.65 mg/dL; Immunoglobulin G 6.93 g/L; Immunoglobulin A 1.28 g/L; Immunoglobulin M 0.27 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 65 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 6.2 g/dL; Glucose 5.34 mmol/L.
- Day 724 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 3.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.56 mg/dL; Immunoglobulin G 6.52 g/L; Immunoglobulin A 1.5 g/L; Immunoglobulin M 0.17 g/L; Hemoglobin 7.69 mmol/L; Leukocytes 1.7 ×10⁹/L; Absolute Neutrophil 0.8 ×10⁹/L; Platelets 63 ×10⁹/L; Creatinine 130 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.08 mmol/L; Albumin 40.9 g/L; Total Protein 6.6 g/dL; Glucose 5.12 mmol/L.
- Day 820 (ECOG 1): Immunoglobulin G 7.34 g/L; Immunoglobulin A 1.73 g/L; Immunoglobulin M 0.22 g/L; Hemoglobin 7.69 mmol/L; Leukocytes 2.44 ×10⁹/L; Absolute Neutrophil 1.59 ×10⁹/L; Platelets 71 ×10⁹/L; Creatinine 122 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.03 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 7.21 mmol/L.

Other clinical attributes
- Day -5: Weight: 76 kg; Height: 174 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2352_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_2352_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
